Surgical pathology report (de-identified scan), TCGA case TCGA-AP-A05A, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site MSKCC, specimen TCGA-AP-A05A-01A (Primary Tumor).

[page 1 of 2]
1CD-0-3

Specimens Submitted:

- 1: SP: Uterus, cervix, bilateral tubes and ovaries
- 2: SP: Omentum (pjm)
- 3: SP: Left external iliac lymph nodes
- 4: SP: Left obturator lymph nodes
- 5: SP: Left internal iliac lymph nodes
- 6: SP: Portion of right round ligament
- 7: SP: Right external iliac lymph nodes
- 8: SP: Right hypogastric lymph nodes
- 9: SP: Right obturator lymph nodes
- 10: SP: Gallbladder

adenocarcinoma, serous, NOS 8441/3
Site: endometrium C54.1 bu 5/2/11

DIAGNOSIS:

1. UTERUS, CERVIX, FALLOPIAN TUBES AND OVARIES; TOTAL HYSTERECTOMY AND BILATERAL SALPINGO-OOPHORECTOMY:
- ADENOCARCINOMA OF ENDOMETRIUM, PAPILLARY SEROUS TYPE.
- THE TUMOR INVADERS ALMOST THE ENTIRE THICKNESS OF THE MYOMETRIUM.
- THE MAXIMAL THICKNESS OF MYOMETRIAL INVASION IS 10 MM.
- THE THICKNESS OF THE MYOMETRIUM IN THE AREA OF MAXIMAL TUMOR INVASION IS 11MM.
- ENDOCERVICAL INVASION IS PRESENT BOTH IN THE MUCOSA AND THE STROMA TO A DEPTH OF <1 MM.
- VASCULAR INVASION IS PRESENT.
- THE ENDOMETRIUM SHOWS THE FOLLOWING ABNORMALITY: CYSTIC ATROPHY.
- THE MYOMETRIUM SHOWS THE FOLLOWING ABNORMALITY: LEIOMYOMATA.
- ALL ADNEXAE ARE UNREMARKABLE.
2. OMENTUM; OMENTECTOMY:
- BENIGN ADIPOSE TISSUE.
3. LYMPH NODES, LEFT EXTERNAL ILIAC; EXCISION:
- ONE BENIGN LYMPH NODE (0/1).
4. LYMPH NODES, LEFT OBTURATOR; EXCISION:

** Continued on next page **

bu 5/2/11

[page 2 of 2]
-
- ONE BENIGN LYMPH NODE (0/1).
5. LYMPH NODES, LEFT INTERNAL ILIAC; EXCISION:
- BENIGN FIBROADIPOSE TISSUE.
- NO LYMPHOID TISSUE IS IDENTIFIED IN THE ENTIRELY SUBMITTED SPECIMEN.
6. ROUND LIGAMENT, RIGHT; BIOPSY
- BENIGN FIBROMUSCULAR TISSUE.
7. LYMPH NODES: RIGHT EXTERNAL ILIAC; EXCISION:
- ONE BENIGN LYMPH NODE (0/1).
8. LYMPH NODES, RIGHT HYPOGASTRIC; EXCISION:
- ONE BENIGN LYMPH NODE (0/1).
9. LYMPH NODES, RIGHT OBTURATOR; EXCISION:
- TWO BENIGN LYMPH NODES (0/2).
10. GALLBLADDER; CHOLECYSTECTOMY
- CHRONIC CHOLECYSTITIS.
- CHOLELITHIASIS.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

Source: NCI Genomic Data Commons file 75432d33-dd61-40fc-a0ef-98f7ea66f75c (TCGA-AP-A05A.1DAE9968-7D20-45A9-B2BC-5F32F6EC7A08.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).